Somatic mutation profile of tumor specimen TCGA-KN-8433-01A (aliquot TCGA-KN-8433-01A-11D-2310-10) from TCGA case TCGA-KN-8433, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 46.8 years (17,108 days).
Specimen TCGA-KN-8433-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4639c9a6-4024-4d25-9853-9e0ea9271d04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8433-11A (Solid Tissue Normal), aliquot TCGA-KN-8433-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43dfc52d-9fa9-4f3e-9652-fd7f0b9aa24b

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Ins 3, Nonsense Mutation 2, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 30/69 reads (43%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C5 | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 113/198 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1333670287, COSV99796964; called by muse, mutect2, varscan2
- CACNA1A | c.3108C>A p.N1036K | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs759093387, COSV100800384; called by muse, mutect2, varscan2
- CFAP69 | c.2508G>T p.W836C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100289693; called by muse, mutect2
- CHUK | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV64918378; called by muse, mutect2, varscan2
- GLUD2 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1366485762, COSV100046561, COSV60151499; called by muse, mutect2, varscan2
- RNASEH2A | c.104A>T p.E35V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99677203; called by muse, mutect2, varscan2
- RUNX2 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as CD053603, COSV100767062; called by muse, mutect2, varscan2
- SCRIB | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 4/65 reads (6%) | catalogued as COSV57584010; called by muse, mutect2
- WDR49 | c.1403T>A p.I468K (on ENST00000308378 / NM_001366158.1; = p.I809K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV100391355; called by muse, mutect2
- WWP1 | c.477A>C p.E159D | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV99615466; called by muse, mutect2, varscan2
- ZZEF1 | c.8249A>T p.D2750V | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101067400; called by muse, mutect2, varscan2
- HCN1 | c.2671dup p.*891Lfs*36 | Frame Shift Ins (INS) | VAF 29/58 reads (50%) | called by mutect2, varscan2
- HCN1 | c.2669dup p.L890Ffs*37 | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | called by mutect2*, pindel, varscan2*
- SLK | c.1099dup p.T367Nfs*4 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- SLA2 | c.147C>T p.A49= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as rs374910927; called by muse, mutect2, varscan2
